Somatic mutation profile of tumor specimen TCGA-OR-A5JX-01A (aliquot TCGA-OR-A5JX-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JX, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 50.4 years (18,402 days).
Specimen TCGA-OR-A5JX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0d8635c-a994-43cf-85c6-85a344f71d54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JX-10B (Blood Derived Normal), aliquot TCGA-OR-A5JX-10B-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85393a18-1dfb-450e-923f-42216c9b5554

The open-access MAF lists 31 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, Nonsense Mutation 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP11 | c.1523A>G p.H508R | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV99214235; called by muse, mutect2, varscan2
- COL14A1 | c.3358C>T p.R1120* | Nonsense Mutation (SNP) | VAF 40/220 reads (18%) | catalogued as rs779378321, COSV52852069, COSV52861310; called by muse, mutect2, varscan2
- CYSLTR2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201503697; called by muse, mutect2, varscan2
- IQUB | c.1603C>T p.Q535* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as rs745426564, COSV100227244; called by muse, mutect2, varscan2
- KLHL28 | c.955A>G p.I319V | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1179943912; called by muse, mutect2, varscan2
- PDZRN4 | c.2047A>G p.I683V (on ENST00000402685 / NM_001164595.2; = p.I425V on NM_013377.4) | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as rs751570104; called by muse, varscan2
- TENM3 | c.2077G>C p.G693R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.474); catalogued as rs1036616870; called by muse, mutect2, varscan2
- AC098582.1 | c.1615A>T p.N539Y | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ANKRD35 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ATG2B | c.1028C>G p.S343C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP8A1 | c.2539C>T p.H847Y | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- BTN3A1 | c.667A>T p.R223* | Nonsense Mutation (SNP) | VAF 9/182 reads (5%) | called by muse, mutect2
- CADPS2 | c.2572C>G p.H858D | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDC73 | c.877T>G p.Y293D | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FANCM | c.2020C>A p.L674I | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GALNTL6 | c.1765A>G p.M589V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- JAKMIP3 | c.1298T>A p.L433Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NTRK2 | c.1999C>G p.L667V (on ENST00000323115 / NM_001369534.1; = p.L683V on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMC4 | c.2958C>G p.I986M | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SYCP2 | c.4202A>C p.H1401P | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- TAB3 | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 95/209 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- TENM3 | c.5582G>A p.S1861N | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- TLL1 | c.1868C>A p.T623N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); called by mutect2, varscan2
- TMEM30A | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC22 | c.561C>T p.P187= | Silent (SNP) | VAF 69/146 reads (47%) | called by muse, mutect2, varscan2
- DMD | c.7399T>C p.L2467= | Silent (SNP) | VAF 12/125 reads (10%) | called by muse, mutect2, varscan2
- FAM172A | c.1101C>T p.V367= | Silent (SNP) | VAF 57/383 reads (15%) | called by muse, mutect2, varscan2
- MRPL32 | c.7C>T p.L3= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as rs773260503; called by muse, mutect2, varscan2
- POU2F2 | c.420G>A p.P140= | Silent (SNP) | VAF 29/149 reads (19%) | catalogued as rs375042716; called by muse, mutect2, varscan2
- TMC5 | c.2286G>C p.L762= (on ENST00000396229 / NM_001105248.1; = p.L516= on NM_024780.5) | Silent (SNP) | VAF 47/227 reads (21%) | catalogued as COSV54911075; called by muse, mutect2, varscan2
- SNX18 | c.*8C>A | 3'UTR (SNP) | VAF 64/192 reads (33%) | catalogued as COSV100543523; called by muse, mutect2, varscan2
